Somatic mutation profile of tumor specimen TCGA-06-0686-01A (aliquot TCGA-06-0686-01A-01D-1492-08) from TCGA case TCGA-06-0686, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,503 days).
Specimen TCGA-06-0686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54e523b5-4bb4-434f-84f4-dce4932b793a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0686-10A (Blood Derived Normal), aliquot TCGA-06-0686-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba398aa0-52ca-43c4-8ea8-d3774333ef30

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 15, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM22 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.676); catalogued as COSV55977782; called by muse, mutect2, varscan2
- ALLC | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1276153447, COSV52994830; called by muse, mutect2, varscan2
- ALPG | c.376T>C p.F126L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV54966265; called by muse, mutect2, varscan2
- AP3B1 | c.3032T>C p.I1011T | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54884458; called by muse, mutect2, varscan2
- AZGP1 | c.874G>C p.V292L | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV52799334; called by muse, mutect2, varscan2
- BCORL1 | c.4109C>T p.S1370F | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV54406425; called by muse, mutect2
- BMP15 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 56/69 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53140591; called by muse, mutect2, varscan2
- C8orf34 | c.1326C>T p.F442= | Splice Region (SNP) | VAF 20/33 reads (61%) | catalogued as rs201463505, COSV57396967; called by muse, mutect2, varscan2
- CCNE2 | c.549T>G p.N183K | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV57376182; called by muse, mutect2, varscan2
- CD7 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536476554, COSV53939531; called by muse, mutect2, varscan2
- CFAP161 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV54429392; called by muse, mutect2, varscan2
- CFAP74 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs766114699, COSV54568567; called by muse, mutect2, varscan2
- COL14A1 | c.4472G>A p.R1491Q | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs142082215, COSV99921277; called by muse, mutect2
- COL22A1 | c.4498G>T p.G1500W | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57359307; called by muse, mutect2
- CRELD1 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.946); catalogued as COSV55978583; called by muse, mutect2, varscan2
- DENND2C | c.1013C>A p.A338E | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.111); catalogued as COSV67923976; called by muse, mutect2
- FRYL | c.8592+2T>G p.X2864_splice | Splice Site (SNP) | VAF 9/121 reads (7%) | catalogued as COSV51944290, COSV51961689; called by muse, mutect2
- FRYL | c.6394-2A>G p.X2132_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | catalogued as COSV51961707; called by muse, mutect2, varscan2
- GABRG2 | c.238A>G p.K80E | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV62718371; called by muse, mutect2, varscan2
- GFI1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV54043898; called by muse, mutect2, varscan2
- HHIPL2 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 102/241 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV58565417; called by muse, mutect2, varscan2
- IL15RA | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 58/71 reads (82%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV66092730; called by muse, mutect2, varscan2
- INHBE | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 369/408 reads (90%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1458340123, COSV56988215, COSV99875352; called by muse, mutect2, varscan2
- MRE11 | c.1385T>A p.V462E | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60580137; called by muse, mutect2
- MUC16 | c.38255G>A p.R12752K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.824); catalogued as COSV67491719; called by muse, mutect2, varscan2
- MYH11 | c.2339A>G p.E780G | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55568873; called by muse, mutect2
- NEK3 | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51619298; called by muse, mutect2, varscan2
- NPY5R | c.1225A>G p.I409V | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as rs754248718, COSV58452143; called by muse, mutect2, varscan2
- OR2H1 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759165826, COSV65810709; called by muse, mutect2, varscan2
- OR4S2 | c.909T>A p.N303K | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56747048; called by muse, mutect2, varscan2
- PAQR4 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs367647268; called by muse, mutect2, varscan2
- PCDHA13 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV56477337; called by muse, mutect2
- PDGFRB | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758280032, COSV55805130; called by muse, mutect2, varscan2
- PIWIL4 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV54412393; called by muse, mutect2
- PPIC | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs371579770, COSV100120614; called by muse, mutect2, varscan2
- RBBP6 | c.4540A>C p.K1514Q | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV60505355; called by muse, mutect2, varscan2
- RBMXL1 | c.1100G>A p.S367N | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); catalogued as COSV53101521; called by muse, mutect2, varscan2
- SLC12A2 | c.3314A>G p.E1105G | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1470718426, COSV52471699; called by muse, mutect2, varscan2
- SMARCD2 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as rs367946883, COSV56739479; called by muse, mutect2, varscan2
- SNAP47 | c.423T>A p.H141Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59919988; called by muse, mutect2, varscan2
- TGFA | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 68/156 reads (44%) | catalogued as rs782253342, COSV54913863; called by muse, mutect2, varscan2
- TRIML1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60194468; called by muse, mutect2, varscan2
- TTN | c.66985C>T p.R22329W (on ENST00000591111; = p.R14905W on NM_003319.4) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | PolyPhen probably damaging (0.999); catalogued as rs748041610, COSV59932620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.28889T>G p.F9630C (on ENST00000591111; = p.F8703C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | PolyPhen possibly damaging (0.487); catalogued as COSV60330856; called by muse, mutect2, varscan2
- UBQLN3 | c.922T>A p.S308T | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV61165652; called by muse, mutect2
- ZNF23 | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV61841006; called by muse, mutect2, varscan2
- ZNF493 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62750185; called by muse, mutect2, varscan2
- TRPV6 | c.1485del p.F496Lfs*20 | Frame Shift Del (DEL) | VAF 36/180 reads (20%) | called by mutect2, pindel, varscan2
- ABCA8 | c.666T>A p.T222= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as rs1048344720, COSV52202227; called by muse, mutect2, varscan2
- CHD7 | c.7470G>A p.S2490= | Silent (SNP) | VAF 86/217 reads (40%) | catalogued as rs780608336, COSV101418378, COSV71111008; called by muse, mutect2, varscan2
- CNTNAP5 | c.3558G>A p.A1186= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs764532960, COSV70487736; called by muse, mutect2, varscan2
- CYP4F3 | c.456G>A p.T152= | Silent (SNP) | VAF 56/118 reads (47%) | catalogued as rs138865516; called by muse, mutect2, varscan2
- ENPP2 | c.2523G>A p.K841= (on ENST00000075322 / NM_001040092.3; = p.K893= on NM_006209.5) | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as COSV50011824, COSV50015989; called by muse, mutect2, varscan2
- GHSR | c.207G>A p.S69= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as rs995230051, COSV53838664, COSV53838892, COSV53839470; called by muse, mutect2, varscan2
- GPR150 | c.726C>T p.V242= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV66168594; called by muse, mutect2, varscan2
- HHIPL1 | c.450C>T p.S150= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as rs1410257179, COSV58092836; called by muse, mutect2
- ISLR | c.1245G>C p.L415= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV51433946; called by muse, mutect2, varscan2
- KCNB2 | c.1998G>A p.T666= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as rs1277870040, COSV73050439, COSV73051069; called by muse, mutect2, varscan2
- KCNRG | c.33G>C p.V11= | Silent (SNP) | VAF 65/148 reads (44%) | catalogued as COSV53949672; called by muse, mutect2, varscan2
- LARGE2 | c.543A>C p.L181= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV57654352; called by muse, mutect2, varscan2
- OR6F1 | c.426G>A p.A142= | Silent (SNP) | VAF 77/158 reads (49%) | catalogued as rs373540517; called by muse, mutect2, varscan2
- PDE1C | c.1425G>A p.S475= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as rs763131623, COSV58515001; called by muse, mutect2, varscan2
- ZNF184 | c.378A>C p.I126= | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as COSV53004394; called by muse, mutect2, varscan2
- CIRBP | c.-7+533C>T | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- SNORD114-20 | n.6C>T | RNA (SNP) | VAF 30/92 reads (33%) | catalogued as rs1369080429; called by muse, mutect2, varscan2
